Somatic mutation profile of tumor specimen TCGA-CS-4941-01A (aliquot TCGA-CS-4941-01A-01D-1468-08) from TCGA case TCGA-CS-4941, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Brain, NOS; Tumor grade: G3; Age at diagnosis: 67.3 years (24,578 days).
Specimen TCGA-CS-4941-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a3e24b5-f567-4985-b817-200562bb7c1b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CS-4941-10A (Blood Derived Normal), aliquot TCGA-CS-4941-10A-01D-1468-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/117ef787-7544-464e-a3f2-9e45cf7ac7f3

The open-access MAF lists 49 somatic variants for this specimen: 42 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 6, Nonsense Mutation 4, Splice Site 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RPGRIP1L | c.2305-1G>A p.X769_splice | Splice Site (SNP) | VAF 22/70 reads (31%) | catalogued as rs863225215, CS073524, COSV50913586; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCG1 | c.1138C>T p.R380* | Nonsense Mutation (SNP) | VAF 22/217 reads (10%) | catalogued as rs577566323, COSV59208909; called by muse, mutect2, varscan2
- ACAD8 | c.730C>G p.R244G | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as rs746960051, COSV55540453, COSV55542140; called by mutect2, varscan2
- ADAM7 | c.1655+2T>A p.X552_splice | Splice Site (SNP) | VAF 26/86 reads (30%) | catalogued as COSV51544733; called by muse, mutect2, varscan2
- ADAM7 | c.1663A>T p.R555* | Nonsense Mutation (SNP) | VAF 15/82 reads (18%) | catalogued as COSV51544759; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3338T>A p.L1113Q | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV65896660; called by muse, mutect2, varscan2
- ALDH1B1 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 47/194 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs770857076, COSV66619516; called by muse, mutect2, varscan2
- ANKRD34A | c.499G>A p.G167R | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.796); catalogued as rs201078779, COSV60161771; called by muse, mutect2, varscan2
- ANKRD44 | c.1613A>C p.Y538S | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56562644; called by muse, mutect2, varscan2
- ARHGAP26 | c.1898G>A p.S633N | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.827); catalogued as COSV50836713; called by muse, mutect2, varscan2
- BIN1 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.087); catalogued as rs1558835946, COSV52121114; called by muse, mutect2, varscan2
- CDK5RAP2 | c.5603G>A p.R1868Q | Missense Mutation (SNP) | VAF 6/77 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752717425, COSV62577078; called by muse, mutect2
- CENATAC | c.719C>G p.A240G | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57722390, COSV57723573; called by muse, mutect2, varscan2
- CLASP1 | c.3451G>A p.A1151T | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.154); catalogued as rs778656548, COSV55322159; called by muse, mutect2, varscan2
- DDX3X | c.1048C>T p.R350W (on ENST00000399959; = p.R351W on NM_001356.5) | Missense Mutation (SNP) | VAF 65/127 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV67864267; called by muse, mutect2, varscan2
- DENND1C | c.1459C>T p.P487S | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV57568974; called by muse, mutect2
- DNAH11 | c.6209T>C p.I2070T | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV60973436; called by muse, mutect2, varscan2
- DNHD1 | c.11390G>A p.R3797Q | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs377176360; called by muse, mutect2, varscan2
- DNHD1 | c.11684G>A p.R3895H | Missense Mutation (SNP) | VAF 51/177 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs376727342; called by muse, mutect2, varscan2
- EFEMP2 | c.229G>A p.G77S | Missense Mutation (SNP) | VAF 46/215 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57261222; called by muse, mutect2, varscan2
- EFR3A | c.790C>G p.H264D | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV54461002; called by muse, mutect2, varscan2
- ERI3 | c.455A>C p.E152A | Missense Mutation (SNP) | VAF 172/434 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64833094; called by muse, mutect2, varscan2
- GARRE1 | c.2147G>A p.G716E | Missense Mutation (SNP) | VAF 59/215 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.124); catalogued as COSV55102704; called by muse, mutect2, varscan2
- GK2 | c.380G>A p.S127N | Missense Mutation (SNP) | VAF 63/237 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as COSV62628009; called by muse, mutect2, varscan2
- IKBKE | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.809); catalogued as rs143140330, COSV65624638; called by muse, mutect2, varscan2
- KRT222 | c.721C>T p.R241* | Nonsense Mutation (SNP) | VAF 37/129 reads (29%) | catalogued as rs1031174264, COSV67498158; called by muse, mutect2, varscan2
- KRTAP21-2 | c.17A>G p.Y6C | Missense Mutation (SNP) | VAF 56/173 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.416); catalogued as rs145167151; called by muse, mutect2, varscan2
- MGAM | c.2146C>T p.R716C | Missense Mutation (SNP) | VAF 98/429 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782806699, COSV72074552; called by mutect2, varscan2
- MTERF3 | c.1009G>A p.V337M | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV54634047; called by muse, mutect2, varscan2
- PAPPA2 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 120/263 reads (46%) | catalogued as rs557625059, COSV100867139, COSV62772170; called by muse, mutect2, varscan2
- PEAR1 | c.2795C>T p.P932L | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV52775105; called by muse, mutect2, varscan2
- PLCG1 | c.3487G>A p.E1163K | Missense Mutation (SNP) | VAF 57/183 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV54815150; called by muse, mutect2, varscan2
- RGS21 | c.94C>A p.L32I | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.415); catalogued as COSV69883480; called by muse, mutect2, varscan2
- RTL9 | c.1489A>T p.M497L | Missense Mutation (SNP) | VAF 73/144 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs764213416, COSV71826106; called by muse, mutect2, varscan2
- SERPINB7 | c.130T>A p.L44M | Missense Mutation (SNP) | VAF 43/146 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.55); catalogued as COSV60535294; called by muse, mutect2, varscan2
- SMARCA1 | c.1300G>C p.D434H | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64413321; called by muse, mutect2, varscan2
- TNNT1 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as rs367977700, COSV52570945; called by muse, mutect2, varscan2
- TPP2 | c.2594G>C p.R865T | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.425); catalogued as COSV65754280; called by muse, mutect2, varscan2
- TTN | c.51103C>T p.P17035S (on ENST00000591111; = p.P9611S on NM_003319.4) | Missense Mutation (SNP) | VAF 45/202 reads (22%) | PolyPhen probably damaging (0.998); catalogued as COSV60261513; called by muse, mutect2, varscan2
- ZNF366 | c.1103T>C p.V368A | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.354); catalogued as COSV59218165; called by muse, mutect2, varscan2
- ZNF675 | c.1591A>T p.T531S | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.049); catalogued as COSV63097123; called by muse, mutect2, varscan2
- POLR2A | c.4073C>T p.T1358M | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- CAVIN2 | c.297G>A p.K99= | Silent (SNP) | VAF 22/77 reads (29%) | catalogued as rs748435720, COSV58425250; called by muse, mutect2, varscan2
- CD82 | c.654G>A p.E218= | Silent (SNP) | VAF 25/111 reads (23%) | catalogued as COSV57036866; called by muse, mutect2, varscan2
- CDH9 | c.2208A>C p.A736= | Silent (SNP) | VAF 70/200 reads (35%) | catalogued as COSV50388033; called by muse, mutect2, varscan2
- FLG | c.11643G>A p.E3881= | Silent (SNP) | VAF 43/207 reads (21%) | catalogued as COSV64246236; called by muse, mutect2, varscan2
- NBL1 | c.228A>C p.T76= | Silent (SNP) | VAF 36/108 reads (33%) | catalogued as COSV57030933; called by muse, mutect2, varscan2
- ZNF536 | c.2433G>A p.P811= | Silent (SNP) | VAF 38/152 reads (25%) | catalogued as rs371262692; called by muse, mutect2, varscan2
- CCHCR1 | c.-51-509G>A | Intron (SNP) | VAF 6/23 reads (26%) | catalogued as COSV66161633; called by muse, mutect2, varscan2
